Surgical pathology report (de-identified scan), TCGA case TCGA-V4-A9EF, project TCGA-UVM (Uveal Melanoma), tissue source site Institut Curie, specimen TCGA-V4-A9EF-01A (Primary Tumor).

Date of surgery :

Right eye enucleation

Macroscopy

The enucleation specimen measures 25 mm in diameter. It includes a segment of optic nerve of 10 mm associated to 25 mm of fat tissue. At the section, a large black tumor of the posterior pole is found, measuring 16 by 13 mm. Samples have been made for cryopreservation and for cytogenetic studies.

Microscopy

The tumor described macroscopically correspond to a melanoma. It is made mostly of fusiform cells with ovale nucleus most often nucleolated. Mitotic figures are present (4 mitosis by 10 fields at the 400 magnification). Absence of necrosis or microcalcification. The tumor is developed immediately behind the ciliary body which is sometimes infiltrated. The internal third of the sclera is infiltrated. The iris and the anterior chamber as well as the optic nerve on its entire course and the meningeal sheaths are free.

Conclusion

Melanoma with fusiform cells developed behind the ciliary body which is infiltrated sometimes on the entire thickness.

Size of the tumor: 16 mm main line

Extension to the internal third of the sclera without extrascleral extension

The iris and the anterior chamber as well as the optic nerve on its entire course and the meningeal sheaths are free.

Clinical	hw 12/30/13	Yes	No
HPV Discrepancy			
Prior Site Discrepancy			
Case is (check)			

Source: NCI Genomic Data Commons file c215895a-e5dc-430c-8b90-dc26d228aa2d (TCGA-V4-A9EF.816380AA-CC87-4221-B41C-9A02E2201D02.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).